Surgical pathology report (de-identified scan), TCGA case TCGA-HV-A7OP, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HV-A7OP-01A (Primary Tumor).

M/

CLINICAL DIAGNOSIS : Pancreatic Cancer

FROZEN DIAGNOSIS :

- Fro 1) R/O liver mass, biopsy: Mesothelial cell hyperplasia
Fro 2) R/O peritoneal seeding #1, biopsy: Negative
Fro 3) R/O peritoneal seeding #2, biopsy: Atypical glands
Fro 4) R/O peritoneal seeding #3, biopsy: No tumor present
Fro 5) R/O peritoneal seeding #4, biopsy: No tumor present
Fro 6) Omental seeding, biopsy: No tumor present in lymph node
Fro 7) Pancreatic resection margin, biopsy: Negative

ICD-O-3
~~Adenocarcinoma~~ duct NOS
8500/3
tubulopapillary
8263/3
Code to highest 8500/3
Site Pancreas head C25.0
9/26/13

DIAGNOSIS:

Pancreas, duodenum and common bile duct, pancreatco-duodenectomy:

Intraductal tubulopapillary neoplasm, invasive, pancreas head

- 1) Size of tumor: 6.5x5.0x5.0cm
- 2) Extent of invasion: invasion to duodenum and ampulla of Vater
- 5) Blood vessel invasion: absent
- 6) Lymphatic invasions: present
- 7) Perineural invasion: present
- 8) Surgical margins: free (safety margin: 6.5cm from common bile duct margin,
0.1cm from retroperitoneal margin,
3.5cm from duodenum proximal margin,
5.0cm from pancreas resection margin)
- 9) Lymph node: metastasis in 7 out of 28 lymph nodes
(mesenteric LN: 1/7, pericholedochal LN: 0/2, inferior head LN: 1/2, LN: 0/0,
LN #8: 0/6, LN #12: 0/0, LN #13: 1/1, LN #16: 0/5, LN #17: 4/5, omentum: 0/0)
- 10) Pathologic stage: pT3N1
- 11) Related slide:
- 12) Associated findings: Pan IN 3 in remaining pancreatic parenchyma

Tissue labeled "R/O liver mass", biopsy: Mesothelial cell hyperplasia

Tissue labeled "R/O peritoneal seeding #2", biopsy: Atypical glands

Tissue labeled "R/O peritoneal seeding #1, #3, #4", biopsy: No tumor present

Tissue labeled "omental seeding", biopsy: No tumor present

Gallbladder, cholecystectomy: Chronic cholecystitis

Soft tissue, omentum, omentectomy: No tumor present

IIA/IIIA Discrepancy		✓

Source: NCI Genomic Data Commons file d8495227-089e-4e5e-9727-c456d695c6c7 (TCGA-HV-A7OP.9CF238DA-57D1-4DDF-9ECB-23BC9F887056.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).